Somatic mutation profile of tumor specimen TCGA-KK-A59V-01A (aliquot TCGA-KK-A59V-01A-11D-A29Q-08) from TCGA case TCGA-KK-A59V, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,483 days).
Specimen TCGA-KK-A59V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5f11225-94ce-4428-be6f-d6a93d16eca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A59V-11A (Solid Tissue Normal), aliquot TCGA-KK-A59V-11A-11D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04fac7e-cba5-4183-b368-fe532432c988

The open-access MAF lists 913 somatic variants for this specimen: 698 protein-altering or splice-affecting, 198 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 467, Silent 198, Frame Shift Del 162, Nonsense Mutation 27, Frame Shift Ins 27, Intron 9, Splice Site 6, Splice Region 5, In Frame Del 4, RNA 4, 3'UTR 3, 5'Flank 1.

Variants (750 of 913; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by pindel, varscan2
- FASLG | c.263del p.F88Sfs*8 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs587776450; ClinVar: pathogenic; called by mutect2, pindel
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MTM1 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs587783805, CM001733, COSV60335653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5422G>A p.G1808S | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs369940645, CM1310646; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PCDH19 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as rs769967221, CM1211675, COSV55257472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.6172del p.S2058Lfs*19 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs1214399996, CD056852, CD1111485; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.2791C>T p.R931C (on ENST00000303395 / NM_001202435.3; = p.R920C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121918788, CM024303, COSV57687876; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.4423G>A p.G1475R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as rs796053216, COSV61993169; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SLC6A1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs1403165900, COSV55114730; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV50746365; called by muse, mutect2, varscan2
- ABL1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191034511, COSV59325948; called by muse, mutect2, varscan2
- ABTB1 | c.836C>T p.A279V (on ENST00000232744 / NM_172027.3; = p.A137V on NM_032548.3) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV51742958; called by muse, mutect2, varscan2
- ACADSB | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV62551483; called by muse, varscan2
- ACCS | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs755451613, COSV55457017; called by muse, mutect2, varscan2
- ACE | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.294); catalogued as rs759167880, COSV52013088; called by muse, mutect2, varscan2
- ACHE | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV53816154; called by muse, mutect2, varscan2
- ACTL6B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50514372; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 47/102 reads (46%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS8 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs763820298, COSV57295275, COSV57297829; called by muse, mutect2, varscan2
- ADAMTSL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs866189730, COSV52825642; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867362950, COSV54469608; called by muse, mutect2, varscan2
- ADCY6 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1313383674, COSV57170562; called by muse, mutect2, varscan2
- ADGRL1 | c.2779G>A p.A927T (on ENST00000340736 / NM_001008701.3; = p.A922T on NM_014921.5) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1277016672, COSV61566677; called by muse, mutect2, varscan2
- ADGRV1 | c.18298A>G p.T6100A | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as rs747453534, COSV67995537; called by muse, varscan2
- ADH6 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs201537738; called by muse, mutect2, varscan2
- ADPRHL1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs902922489, COSV62910940; called by muse, mutect2
- AFF1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57124099; called by muse, mutect2, varscan2
- AGAP3 | c.1991G>A p.C664Y (on ENST00000622464; = p.C700Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68246730; called by muse, varscan2
- AGAP3 | c.2060C>T p.P687L (on ENST00000622464; = p.P723L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368016856; called by muse, varscan2
- AHCYL2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs766038729, COSV61491254; called by muse, mutect2, varscan2
- AHDC1 | c.4681G>A p.D1561N | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV55942410; called by muse, mutect2
- AJAP1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV65454410; called by muse, mutect2, varscan2
- AJUBA | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.089); catalogued as rs200247985, COSV52984352, COSV52986741; called by muse, mutect2, varscan2
- AKAP12 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as rs758119251, COSV53578472; called by muse, mutect2, varscan2
- AL645922.1 | c.1024del p.A342Pfs*9 | Frame Shift Del (DEL) | VAF 43/199 reads (22%) | catalogued as rs752447090, COSV54961301; called by mutect2, varscan2
- AL645922.1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs200645483, COSV54962573; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ALKBH5 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs1403829834, COSV67687372; called by muse, mutect2, varscan2
- ALMS1 | c.4163C>T p.P1388L | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs377354387; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs760195858, COSV58466344; called by muse, mutect2, varscan2
- AMPD3 | c.505G>A p.A169T (on ENST00000396553 / NM_001025389.2; = p.A178T on NM_000480.3) | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs779211791, COSV67332404; called by muse, varscan2
- AMZ1 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs149900602; called by muse, mutect2, varscan2
- AP1M2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754237081, COSV51569463; called by muse, mutect2, varscan2
- APBB2 | c.955C>T p.R319W (on ENST00000295974 / NM_001166050.2; = p.R320W on NM_004307.2) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs538682911, COSV55954670; called by muse, mutect2, varscan2
- ARAP1 | c.1505C>T p.T502M (on ENST00000393609 / NM_001040118.2; = p.T257M on NM_015242.4) | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs544298839, COSV61990034; called by muse, mutect2, varscan2
- ARHGAP44 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs768572384, COSV52402867; called by muse, mutect2, varscan2
- ARHGEF15 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1320261396, COSV62726488; called by muse, mutect2
- ARHGEF2 | c.2513G>A p.R838Q (on ENST00000361247 / NM_001162383.2; = p.R810Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs911479686, COSV58117299; called by muse, mutect2, varscan2
- ARID1A | c.4652G>A p.R1551H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs748819428, COSV61384854; called by muse, mutect2, varscan2
- ARMC4 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1258575248, COSV53468540; called by muse, mutect2, varscan2
- ARNT | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.902); catalogued as rs143491065; called by muse, mutect2
- ARPC5 | c.188del p.P63Lfs*9 | Frame Shift Del (DEL) | VAF 46/232 reads (20%) | catalogued as rs1558122795, COSV54172267; called by mutect2, pindel, varscan2
- ASB13 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs757058806, COSV63092204; called by muse, mutect2, varscan2
- ASIC1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1444302785, COSV57318816; called by muse, mutect2, varscan2
- ASIC4 | c.1043G>A p.G348D (on ENST00000347842 / NM_182847.3; = p.G367D on NM_018674.6) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61733539; called by muse, mutect2, varscan2
- ASTN2 | c.3466T>A p.F1156I (on ENST00000313400 / NM_001365069.1; = p.F1105I on NM_014010.5) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.977); catalogued as COSV56015056; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 106/524 reads (20%) | catalogued as rs35191129; called by mutect2, varscan2
- ATP6V1B1 | c.577del p.H193Tfs*15 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV52270943; called by mutect2, pindel, varscan2
- ATP9A | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58771887; called by muse, mutect2, varscan2
- ATPSCKMT | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs371836379; called by muse, mutect2, varscan2
- ATXN2L | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs150073438; called by muse, mutect2, varscan2
- B4GALNT4 | c.2718C>T p.D906= | Splice Region (SNP) | VAF 19/82 reads (23%) | catalogued as rs779994504, COSV57321550; called by muse, mutect2
- BCL2A1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs138123718, COSV51213512; called by muse, mutect2, varscan2
- BLVRB | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201096602; called by muse, mutect2, varscan2
- BMP5 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1477164536, COSV63701068; called by muse, mutect2, varscan2
- BMP7 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67782682; called by muse, mutect2, varscan2
- BRAF | c.1321A>G p.T441A (on ENST00000288602 / NM_001374244.1; = p.T401A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV56378642; called by muse, mutect2, varscan2
- BRD4 | c.1696A>G p.K566E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV54595116; called by muse, varscan2
- BRICD5 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 28/192 reads (15%) | catalogued as rs374169284; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C14orf180 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs139748841; called by muse, mutect2, varscan2
- C3AR1 | c.104del p.L35Yfs*16 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs767570536; called by mutect2, pindel, varscan2
- C5orf22 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57599989; called by muse, mutect2
- C9orf24 | c.471C>T p.Y157= | Splice Region (SNP) | VAF 61/212 reads (29%) | catalogued as COSV52625506; called by muse, mutect2, varscan2
- CABIN1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747522153, COSV54080159; called by muse, mutect2, varscan2
- CACNA1A | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1431409457, COSV64197078; called by muse, mutect2
- CACNA1D | c.3637G>A p.V1213I (on ENST00000350061 / NM_001128840.3; = p.V1233I on NM_000720.4) | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1205208513, COSV55465013; called by muse, mutect2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CADM3 | c.1174G>A p.D392N (on ENST00000368125 / NM_001127173.3; = p.D426N on NM_021189.5) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs772723270, COSV63673993; called by muse, mutect2, varscan2
- CADPS | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs777645997, COSV51865517; called by muse, mutect2, varscan2
- CADPS | c.3556G>A p.V1186I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as rs574220713, COSV51902999; called by muse, mutect2, varscan2
- CAND2 | c.1061C>T p.A354V (on ENST00000456430 / NM_001162499.2; = p.A261V on NM_012298.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55994738; called by muse, mutect2, varscan2
- CAP2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs759083931, COSV57734949; called by muse, mutect2, varscan2
- CAP2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200559179, COSV57729499; called by muse, mutect2, varscan2
- CASR | c.1696G>A p.V566I (on ENST00000490131; = p.V643I on NM_000388.4) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56141557; called by muse, mutect2, varscan2
- CBX4 | c.958_960del p.K320del | In Frame Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs746909019; called by pindel, varscan2
- CC2D1A | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs559696209, COSV100528683, COSV58786237; called by muse, mutect2, varscan2
- CCDC112 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV65473968; called by muse, mutect2, varscan2
- CCDC130 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs202065091, COSV55583483; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC178 | c.2425C>T p.Q809* (on ENST00000383096 / NM_001105528.3; = p.Q771* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs376925410; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC180 | c.4816G>A p.V1606M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1400916026, COSV63835381; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC86 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 51/169 reads (30%) | catalogued as rs749492752, COSV57126337; called by muse, mutect2, varscan2
- CCER1 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV62648696; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs761073142; called by mutect2, varscan2
- CD160 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV52524395; called by muse, mutect2
- CD81 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.109); catalogued as rs538164293, COSV55134141; called by muse, mutect2, varscan2
- CDC42EP1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs369211517, COSV99312584; called by muse, mutect2, varscan2
- CDH17 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.295); catalogued as rs201617285, COSV50341721, COSV99078686; called by muse, mutect2, varscan2
- CDH23 | c.10054A>T p.T3352S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56490113; called by muse, mutect2, varscan2
- CDKL2 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.155); catalogued as COSV56735476; called by muse, mutect2, varscan2
- CDKN1A | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.863); catalogued as COSV55191500; called by muse, mutect2, varscan2
- CEACAM16 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as rs747285667, COSV69188410; ClinVar: uncertain significance; called by muse, varscan2
- CES3 | c.1629G>T p.W543C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV57594906, COSV57595436; called by muse, mutect2, varscan2
- CFAP61 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs761630843, COSV55647456; called by muse, mutect2, varscan2
- CHD5 | c.4861C>T p.R1621W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs772221709, COSV52412579; called by muse, mutect2, varscan2
- CHD8 | c.2515G>A p.G839R (on ENST00000646647 / NM_001170629.2; = p.G560R on NM_020920.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67872719; called by muse, mutect2
- CHRNA6 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1475918111, COSV52381070; called by muse, mutect2
- CINP | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs374421517; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLPB | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1460448899, COSV53633711; called by muse, mutect2, varscan2
- CLTCL1 | c.3109C>A p.R1037S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV54225426, COSV54239406; called by muse, mutect2, varscan2
- CMBL | c.215+1G>A p.X72_splice | Splice Site (SNP) | VAF 30/95 reads (32%) | catalogued as rs762782155, COSV56985064; called by muse, mutect2, varscan2
- CNNM4 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs374698559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55367525, COSV55368459; called by muse, mutect2, varscan2
- CNOT7 | c.35T>G p.I12S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61353445; called by muse, mutect2, varscan2
- CNTROB | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs763290328, COSV58051202; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A2 | c.3782G>A p.G1261D (on ENST00000341947 / NM_080680.3; = p.G1154D on NM_080679.2) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59502634; called by muse, mutect2, varscan2
- COL11A2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as rs1455937570, COSV59502650; called by muse, mutect2
- COL14A1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs759810359, COSV52850420; called by muse, mutect2, varscan2
- COL16A1 | c.3512G>T p.G1171V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54713894; called by muse, mutect2
- COL22A1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs746394273, COSV57324129; called by muse, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- COLGALT1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1032421349, COSV53111559; called by muse, mutect2
- COX15 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs371107669; called by muse, mutect2, varscan2
- CPB2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs753574889, COSV51676202; called by muse, mutect2
- CPN1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470378071, COSV64942628; called by muse, mutect2, varscan2
- CREBL2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57428032, COSV99963701; called by muse, mutect2, varscan2
- CROCC | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs111474169, COSV100978038, COSV65014875; called by muse, mutect2, varscan2
- CRY2 | c.1726A>G p.K576E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.132); catalogued as COSV69889334; called by muse, mutect2, varscan2
- CSF3R | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV58969251; called by muse, mutect2, varscan2
- CSNK1G1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779009615, COSV57313912; called by muse, mutect2, varscan2
- CTC1 | c.3368G>T p.G1123V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV59855516; called by muse, mutect2, varscan2
- CTNNAL1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs747944532, COSV57702470, COSV57705583; called by muse, mutect2, varscan2
- CTNND2 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139037354; called by muse, mutect2, varscan2
- CTR9 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs764192530, COSV63729173, COSV63729222; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | catalogued as rs756254049; called by mutect2, varscan2
- CYFIP2 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.481); catalogued as COSV59050932, COSV59052862; called by muse, mutect2
- CYP2C18 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs753408877, COSV53675272; called by muse, mutect2, varscan2
- CYP3A7 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60483406; called by muse, mutect2
- CZIB | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV53760393; called by muse, mutect2, varscan2
- DARS2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1064797125, COSV53406433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCTN1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs74768853, COSV62621486; called by muse, mutect2, varscan2
- DDX46 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV62801066; called by muse, mutect2, varscan2
- DEGS2 | c.212T>C p.F71S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59785649; called by muse, mutect2, varscan2
- DENND1C | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs372522125; called by muse, mutect2, varscan2
- DGKB | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769123908, COSV51785301, COSV51813088, COSV99337863; called by muse, mutect2, varscan2
- DHRS1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773189484, COSV55385840; called by muse, mutect2, varscan2
- DHX30 | c.577G>A p.E193K (on ENST00000445061 / NM_138615.3; = p.E154K on NM_014966.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.537); catalogued as rs1001238876, COSV62396663; called by muse, mutect2, varscan2
- DHX33 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs754885958, COSV56577722; called by muse, mutect2, varscan2
- DIDO1 | c.6326C>T p.A2109V | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV56618430; called by muse, mutect2, varscan2
- DIO2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV101375864, COSV70446521; called by mutect2, varscan2
- DISP1 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs148545972, COSV52658687; called by muse, mutect2, varscan2
- DKKL1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778516135, COSV55563888, COSV99678593; called by muse, mutect2, varscan2
- DLL3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs368487646; called by muse, mutect2, varscan2
- DMWD | c.1366del p.L456Wfs*203 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs746317972; called by mutect2, varscan2
- DNAH10 | c.4579del p.T1527Rfs*4 (on ENST00000409039; = p.T1466Rfs*4 on NM_207437.3) | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs1223039312; called by mutect2, pindel, varscan2
- DNAH10 | c.12960C>A p.A4320= (on ENST00000409039; = p.A4259= on NM_207437.3) | Splice Region (SNP) | VAF 6/91 reads (7%) | catalogued as COSV53018620; called by muse, mutect2
- DNAH5 | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs758513686, COSV54205216; ClinVar: uncertain significance; called by muse, mutect2
- DNAJC10 | c.27C>A p.D9E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV51146863, COSV99898944; called by muse, mutect2, varscan2
- DOCK3 | c.3848C>T p.S1283L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs748694483, COSV56549851; called by muse, mutect2, varscan2
- DOP1A | c.314del p.L105Yfs*17 | Frame Shift Del (DEL) | VAF 44/196 reads (22%) | catalogued as rs1162457936; called by mutect2, pindel, varscan2
- DSCAML1 | c.4231C>T p.R1411C (on ENST00000321322; = p.R1351C on NM_020693.4) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs766933373, COSV58390336; called by muse, mutect2, varscan2
- DTX1 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs780785694, COSV55659812; called by muse, mutect2, varscan2
- DYNC1H1 | c.7400G>A p.R2467H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1441059709, COSV64142499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61471504; called by muse, mutect2, varscan2
- EBAG9 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200319904, COSV61753792; called by muse, mutect2, varscan2
- ECI1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as rs746451005, COSV57039552; called by muse, mutect2, varscan2
- EGR1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53518389; called by muse, varscan2
- EHD1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57736799; called by muse, mutect2, varscan2
- EMC10 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.309); catalogued as rs143536282, COSV58543351; called by muse, mutect2
- EP300 | c.6229A>G p.N2077D | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54345644; called by muse, mutect2
- EPHB3 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs370732996, COSV57809123; called by muse, mutect2, varscan2
- EPHX1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs45449793, COSV55304102; called by muse, mutect2, varscan2
- EPN1 | c.1680del p.M561* (on ENST00000270460 / NM_001321263.1; = p.M535* on NM_013333.3) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs1306515040; called by mutect2, varscan2
- ERF | c.1569del p.L525Sfs*6 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as rs1366176199; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- EVA1A | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52062549; called by muse, mutect2, varscan2
- EVI5L | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as rs1271163480, COSV54488774; called by muse, mutect2
- EVX1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1398366276, COSV56086013; called by muse, mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 33/139 reads (24%) | catalogued as rs748159069; called by mutect2, varscan2
- EXOC3L1 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as COSV52048422; called by muse, mutect2, varscan2
- EYA2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs773864573, COSV57946183; called by muse, mutect2, varscan2
- F7 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772383858, COSV60645349, COSV60648059; called by muse, mutect2, varscan2
- FAM102B | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs767990815, COSV64241304; called by muse, mutect2, varscan2
- FAM170A | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.36); catalogued as rs748840322, COSV58927270; called by muse, mutect2, varscan2
- FAM186B | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1253980374, COSV57722400; called by muse, mutect2, varscan2
- FAM214A | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as rs1233955467, COSV55922462; called by muse, mutect2, varscan2
- FAM76B | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57690519; called by muse, mutect2, varscan2
- FAM90A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562876348, COSV56710170; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | catalogued as rs757443519; called by mutect2, varscan2
- FARSB | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs1406256520, COSV56052602; called by muse, mutect2, varscan2
- FBN1 | c.6130T>G p.F2044V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57330552; called by muse, mutect2
- FBXL7 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV61643392; called by muse, mutect2, varscan2
- FBXW9 | c.1336C>T p.R446* (on ENST00000587955; = p.R426* on NM_032301.3) | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs146837377; called by muse, mutect2, varscan2
- FGD3 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV61600046; called by muse, mutect2, varscan2
- FGF9 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66645765; called by muse, mutect2, varscan2
- FGF9 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV66645772; called by muse, mutect2, varscan2
- FHL5 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768547406, COSV58740629; called by muse, mutect2, varscan2
- FILIP1L | c.876G>T p.E292D (on ENST00000354552 / NM_182909.3; = p.E52D on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV58776181; called by muse, mutect2, varscan2
- FKBP8 | c.856G>A p.D286N (on ENST00000222308 / NM_001308373.2; = p.D287N on NM_012181.5) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs778014771, COSV55894124; called by muse, mutect2, varscan2
- FLII | c.2917_2919del p.E973del | In Frame Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs781090764; called by pindel, varscan2
- FSCB | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV61219550; called by muse, mutect2, varscan2
- FSD1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.501); catalogued as rs1568379003, COSV55698944; called by muse, mutect2
- FZR1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs150420576; called by muse, mutect2, varscan2
- GALK1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs372078515, COSV56693488; called by muse, mutect2, varscan2
- GALNS | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs569725890, COSV51940519; called by muse, mutect2, varscan2
- GCAT | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV50650284; called by muse, mutect2, varscan2
- GDPD1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV52384895; called by muse, mutect2, varscan2
- GGT7 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV60542745; called by muse, mutect2, varscan2
- GGTLC1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs755188208, COSV53846183; called by muse, mutect2
- GIGYF2 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV65253571; called by muse, mutect2, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GJA8 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs917690151, COSV53789436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLCCI1 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs374066040, COSV56201767; called by muse, mutect2
- GMDS | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66441949; called by muse, mutect2, varscan2
- GNB1 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as COSV66102019; called by muse, mutect2, varscan2
- GNB4 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV51711866; called by muse, mutect2, varscan2
- GNRHR | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56934893; called by muse, mutect2, varscan2
- GNRHR | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56934900; called by muse, mutect2, varscan2
- GPC1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768758570, COSV50866350; called by muse, mutect2
- GPR153 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775305420, COSV100928423, COSV64939030; called by muse, mutect2, varscan2
- GPR156 | c.842T>C p.L281S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV59942506; called by muse, mutect2
- GPR68 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1183393144, COSV53177462; called by muse, mutect2, varscan2
- GRB14 | c.200del p.K67Rfs*43 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV55738684; called by mutect2, pindel, varscan2
- GUCY2C | c.2221del p.I741Lfs*24 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | catalogued as rs1565608514; called by mutect2, pindel, varscan2
- H2BC21 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58613212; called by muse, mutect2, varscan2
- H6PD | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs761359109, COSV66232343; called by muse, mutect2, varscan2
- HDAC5 | c.695del p.P232Lfs*32 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as COSV56820100; called by mutect2, pindel, varscan2
- HEG1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60765632; called by muse, mutect2
- HEPH | c.1294C>T p.R432* (on ENST00000343002; = p.R165* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV57961523, COSV57962751; called by muse, mutect2
- HERC2 | c.11816+1G>T p.X3939_splice | Splice Site (SNP) | VAF 44/163 reads (27%) | catalogued as COSV55350444; called by muse, mutect2, varscan2
- HGFAC | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs751059415, COSV66977317; called by muse, varscan2
- HIC1 | c.1840G>A p.A614T (on ENST00000322941 / NM_001098202.1; = p.A595T on NM_006497.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV53976320; called by muse, mutect2
- HLX | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs754490132, COSV65044324; called by muse, mutect2
- HOXC10 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV57726112; called by muse, mutect2, varscan2
- HOXD10 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV50895598; called by muse, mutect2, varscan2
- HPN | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs540599600, COSV52882038; called by muse, mutect2, varscan2
- HPS5 | c.457A>T p.N153Y (on ENST00000349215 / NM_181507.2; = p.N39Y on NM_007216.4) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); catalogued as COSV62540662; called by muse, mutect2, varscan2
- HTR4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs199912477, COSV58804814; called by muse, mutect2, varscan2
- ICMT | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104416276, COSV59474611; called by muse, varscan2
- IFNL2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1442692869, COSV59594177; called by muse, mutect2, varscan2
- IGKV1D-16 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | catalogued as rs760534134; called by muse, mutect2, varscan2
- IL16 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57268170; called by muse, mutect2, varscan2
- IL6 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV51733017, COSV51734245; called by muse, mutect2, varscan2
- INPP5D | c.373G>A p.E125K (on ENST00000445964 / NM_001017915.3; = p.E124K on NM_005541.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as rs777393014, COSV64040438; called by muse, mutect2, varscan2
- IQSEC1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs1342413854, COSV56229155; called by muse, mutect2, varscan2
- ITGA2B | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769405222, CM093510, COSV52234560, COSV99289013; called by muse, mutect2, varscan2
- ITGAL | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs755499977, COSV63324384; called by muse, mutect2, varscan2
- ITGB2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs376053062, COSV100185934, COSV56610628; called by muse, mutect2, varscan2
- ITGB6 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs755642266, COSV51795919; called by muse, mutect2, varscan2
- ITSN1 | c.472del p.L158Wfs*37 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as COSV66083080; called by mutect2, pindel, varscan2
- KAT7 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV52013331; called by muse, mutect2
- KBTBD7 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764981841, COSV65266710; called by muse, mutect2
- KCNA5 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767170268, COSV52908801; called by muse, mutect2, varscan2
- KCNH4 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV52921085; called by muse, mutect2, varscan2
- KCNH6 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376994110; called by muse, mutect2, varscan2
- KCNJ2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs947488726, COSV54661553, COSV54663946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.3499G>A p.V1167M (on ENST00000286628 / NM_001161352.2; = p.V1109M on NM_002247.4) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs376264061, COSV54227414; called by muse, mutect2, varscan2
- KCNQ3 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754551218, COSV66463240, COSV66465621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNU1 | c.2704dup p.S902Ffs*40 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | catalogued as rs1176657152; called by pindel, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM5B | c.4601G>A p.R1534H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs536339877, COSV52507424; called by muse, mutect2, varscan2
- KDM6B | c.3643A>T p.I1215F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54687075; called by muse, mutect2, varscan2
- KEAP1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as rs200652594, COSV50375276; called by muse, mutect2, varscan2
- KIAA0100 | c.5719C>T p.R1907C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528597756, COSV56383996; called by muse, mutect2, varscan2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | catalogued as rs767600627; called by mutect2, pindel, varscan2
- KIAA1755 | c.3492del p.R1165Gfs*38 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as rs772495335; called by mutect2, pindel, varscan2
- KIF16B | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs147683391; called by muse, mutect2, varscan2
- KIF1A | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198123218, COSV57483959; called by muse, mutect2
- KIF26B | c.5905G>A p.V1969I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781292387, COSV63646165; called by muse, mutect2, varscan2
- KIF27 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs370478477; called by muse, mutect2, varscan2
- KIF7 | c.3326C>T p.T1109M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs189960711, COSV51546983; called by muse, mutect2, varscan2
- KIF7 | c.1640del p.G547Afs*5 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs770571299, CX113624; called by mutect2, pindel, varscan2
- KIR2DL1 | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV52415457; called by muse, mutect2
- KIRREL2 | c.1953dup p.C652Lfs*49 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | catalogued as rs761116739; called by mutect2, varscan2
- KLHDC10 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs777852524, COSV59052403, COSV59054061; called by muse, mutect2, varscan2
- KLHL36 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377188394, COSV50718043; called by muse, mutect2, varscan2
- KMT5C | c.124del p.L42Cfs*15 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs769842795; called by mutect2, pindel, varscan2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRT78 | c.138del p.C47Afs*40 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs751653006; called by mutect2, pindel, varscan2
- L1CAM | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1377869296, COSV62830168; called by muse, mutect2, varscan2
- LAMA3 | c.4973del p.P1658Lfs*91 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs759440110; called by mutect2, pindel, varscan2
- LAMA4 | c.1541G>A p.R514Q (on ENST00000230538 / NM_001105206.3; = p.R507Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146358872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCA5 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs572580888, COSV63972236; called by muse, mutect2, varscan2
- LIG1 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs747656528, COSV54396073; called by muse, mutect2, varscan2
- LIG1 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs755197772, COSV54393975; called by muse, mutect2, varscan2
- LIG4 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770549827, COSV63596633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIMCH1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as rs1001272864, COSV58274062; called by muse, mutect2, varscan2
- LPCAT4 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1016374423, COSV59219070; called by muse, mutect2, varscan2
- LRRC8A | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.472); catalogued as COSV52189323; called by muse, mutect2, varscan2
- LRRN2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as rs149220897; called by muse, mutect2, varscan2
- MAGI3 | c.3959C>T p.T1320M | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.201); catalogued as rs372079100; called by muse, mutect2, varscan2
- MAN1C1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755018052, COSV56045358; called by muse, mutect2, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAP3K10 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.194); catalogued as rs748551085, COSV53422206; called by muse, mutect2
- MAP3K10 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs368709344; called by muse, mutect2, varscan2
- MAP3K5 | c.3176C>T p.T1059M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs1020957009, COSV62889297; called by muse, mutect2, varscan2
- MAP3K7 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs1421803205, COSV65226033; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3373del p.V1125Wfs*11 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as COSV99169803; called by mutect2, pindel, varscan2
- MARK2 | c.1931G>A p.R644H (on ENST00000402010 / NM_001039469.2; = p.R589H on NM_004954.5) | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs750480856, COSV59289169; called by muse, mutect2, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs751080704; called by mutect2, varscan2
- MATN2 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV54719432; called by muse, mutect2, varscan2
- MCM7 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs532820415, COSV57995461; called by muse, mutect2, varscan2
- MCMBP | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV63509475; called by muse, mutect2, varscan2
- MCOLN2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200938463; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 29/126 reads (23%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV99487865; called by mutect2, pindel, varscan2
- MGP | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.781); catalogued as COSV57454907; called by muse, mutect2
- MIEF1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs1003128148, COSV57477522; called by muse, mutect2, varscan2
- MIEF2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs199876054, COSV59902541; called by muse, mutect2, varscan2
- MLC1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs779394421, COSV61118885; called by muse, varscan2
- MMP21 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64290372; called by muse, mutect2, varscan2
- MMUT | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs565348836, COSV51284048; called by muse, mutect2, varscan2
- MOSPD3 | c.60del p.S21Pfs*21 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs779895385; called by mutect2, pindel, varscan2
- MRGPRX1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV57106460; called by muse, mutect2, varscan2
- MRPL21 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs372240224; called by muse, mutect2, varscan2
- MRPL3 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs764942168, COSV53914432, COSV53914960; called by muse, mutect2, varscan2
- MTMR12 | c.675A>C p.K225N | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV53788080; called by muse, mutect2, varscan2
- MTMR4 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs767960228, COSV60199710; called by muse, mutect2, varscan2
- MUC16 | c.28289del p.N9430Tfs*13 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as rs774904775; called by mutect2, varscan2
- MUC4 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.722); catalogued as rs754656010, COSV62196130; called by muse, mutect2, varscan2
- MUC5B | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1447036523, COSV71589900; called by mutect2, varscan2
- MUSK | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202126269, COSV51896930; called by muse, mutect2
- MYBPC3 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs730880563, COSV57033777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs571377722, COSV53420775; called by muse, mutect2, varscan2
- MYLK4 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755265191, COSV51152728; called by muse, mutect2, varscan2
- MYO15A | c.2873del p.P958Lfs*28 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs1217492313; called by mutect2, pindel
- MYO3A | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV56349678, COSV99780593; called by muse, mutect2
- MYO5A | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs561485938, COSV62557059, COSV62561239; called by muse, mutect2, varscan2
- MYO9A | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748167824, COSV61857927; called by mutect2, varscan2
- MYOM1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV55301270; called by muse, mutect2
- MYOT | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1358850010, COSV53516511, COSV99525167; called by muse, mutect2, varscan2
- MYT1L | c.1174del p.R392Gfs*24 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV101221591; called by mutect2, pindel, varscan2
- NBAS | c.6149G>T p.G2050V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55737782; called by muse, mutect2, varscan2
- NCOR2 | c.5392C>T p.R1798* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs1480147045, COSV62304518; called by muse, mutect2, varscan2
- NDUFB7 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs375409166; called by muse, mutect2, varscan2
- NEB | c.16462T>G p.Y5488D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51460178; called by muse, mutect2, varscan2
- NELFA | c.547G>A p.A183T (on ENST00000542778; = p.A172T on NM_005663.5) | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61604990; called by muse, mutect2, varscan2
- NFS1 | c.1053C>T p.P351= | Splice Region (SNP) | VAF 23/99 reads (23%) | catalogued as rs763462869, COSV65054329; ClinVar: likely benign; called by muse, mutect2, varscan2
- NIBAN2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs371821621; called by muse, mutect2, varscan2
- NIPBL | c.8195G>A p.S2732N | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.262); catalogued as COSV56966158; called by muse, mutect2, varscan2
- NNMT | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs576476423, COSV55474852; called by muse, mutect2, varscan2
- NOL8 | c.840T>A p.N280K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV62638080; called by muse, mutect2, varscan2
- NR2E1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64561688, COSV64562779; called by muse, mutect2, varscan2
- NRBP1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51995947, COSV99274867; called by muse, mutect2
- NRG3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64584183; called by muse, mutect2, varscan2
- NTN1 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1325419572, COSV51488800; called by muse, mutect2, varscan2
- NUDCD3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773373200, COSV58126776; called by muse, mutect2, varscan2
- NUP210L | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs202216243; called by muse, mutect2, varscan2
- NUTM1 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs1323052972, COSV59219062, COSV99043165; called by muse, mutect2, varscan2
- OCRL | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.233); catalogued as rs1333937435, CM165624, COSV63981878; called by muse, mutect2, varscan2
- OFD1 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs376012267, COSV60797653, COSV60798989; called by muse, mutect2, varscan2
- OR12D2 | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs1370298241, COSV65830364; called by muse, mutect2
- OR2D2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762745912, COSV55057129; called by muse, mutect2, varscan2
- OR2M3 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 112/396 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as COSV71759282; called by muse, mutect2, varscan2
- OR52D1 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV59488342; called by muse, mutect2, varscan2
- OTOF | c.4354C>T p.R1452C (on ENST00000272371 / NM_194248.3; = p.R685C on NM_004802.4) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs560665036, COSV55510335; called by muse, mutect2, varscan2
- OVCH1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs755948877, COSV58967968; called by muse, mutect2, varscan2
- PAF1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99656053; called by muse, mutect2
- PAN2 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57756130; called by muse, mutect2, varscan2
- PARP4 | c.2756C>T p.T919I | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1469533320, COSV67964230; called by muse, mutect2, varscan2
- PATL1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs778240780, COSV55692737; called by muse, mutect2, varscan2
- PATZ1 | c.533del p.P178Lfs*12 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | catalogued as COSV53231424; called by mutect2, varscan2
- PCBP4 | c.691G>A p.V231M (on ENST00000322099 / NM_033010.2; = p.V188M on NM_020418.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs773787182, COSV59056164; called by muse, mutect2, varscan2
- PCDH7 | c.295T>A p.C99S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62343574; called by muse, mutect2, varscan2
- PCDHB12 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554286888, COSV53392914; called by muse, mutect2
- PCDHB15 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51070859, COSV51429238; called by muse, mutect2, varscan2
- PCDHB15 | c.1236_1237del p.E412Dfs*34 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | catalogued as rs782340133; called by pindel, varscan2
- PCDHGA6 | c.1936del p.V646Sfs*87 | Frame Shift Del (DEL) | VAF 49/175 reads (28%) | catalogued as COSV99543655; called by mutect2, pindel, varscan2
- PCK2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs112490159, COSV53748137; called by muse, mutect2, varscan2
- PCLO | c.9715C>T p.R3239C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377059138; called by muse, mutect2, varscan2
- PDGFRA | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs904415979, COSV57270073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZD2 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56872656; called by muse, mutect2, varscan2
- PELI2 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50716406; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs752653446, COSV99342923; called by mutect2, varscan2
- PES1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as rs537835882, COSV58829296; called by muse, mutect2, varscan2
- PGBD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs893937684, COSV61401135; called by muse, mutect2, varscan2
- PGM2 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67939578; called by muse, mutect2, varscan2
- PHC2 | c.1645G>A p.G549S (on ENST00000257118 / NM_198040.2; = p.G14S on NM_004427.4) | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs764928189, COSV57101613; called by muse, mutect2, varscan2
- PHF5A | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV53440327; called by muse, mutect2, varscan2
- PHYKPL | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs573140258, COSV100069726, COSV57426326; called by muse, mutect2, varscan2
- PJA1 | c.1190C>T p.P397L (on ENST00000361478 / NM_145119.4; = p.P209L on NM_022368.5) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs180767696, COSV64053758; called by muse, mutect2, varscan2
- PKD1 | c.5071G>A p.G1691S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as rs552542784, COSV51925652; called by muse, mutect2, varscan2
- PLCB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs751256923, COSV62039592; called by muse, mutect2, varscan2
- PLCD4 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.999); catalogued as rs368373841; called by mutect2, varscan2
- PLCG1 | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs767507889, COSV54818395; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60610978, COSV60618210; called by muse, mutect2, varscan2
- PLEC | c.10562C>T p.T3521M (on ENST00000322810 / NM_201380.4; = p.T3411M on NM_000445.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782088523, COSV59695282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.4039C>T p.R1347C (on ENST00000322810 / NM_201380.4; = p.R1237C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs782365536, COSV59695322; called by muse, mutect2, varscan2
- PLEKHG4B | c.2361del p.S788Rfs*19 (on ENST00000283426; = p.S1144Rfs*19 on NM_052909.5) | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs772507185; called by mutect2, pindel, varscan2
- PLK3 | c.1696T>C p.W566R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59501233; called by muse, mutect2, varscan2
- PLPP3 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772751531, COSV64840648; called by muse, mutect2, varscan2
- PLXND1 | c.5657C>T p.P1886L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs375183136; called by muse, mutect2, varscan2
- PNCK | c.278T>C p.V93A (on ENST00000340888 / NM_001366975.1; = p.V176A on NM_001039582.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV61745468; called by muse, mutect2, varscan2
- PNPLA7 | c.2938C>T p.R980W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773536750, COSV53004305; called by muse, mutect2, varscan2
- POGZ | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as rs552308484, COSV55042213; called by muse, mutect2
- POLE | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371882716, COSV57685249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLN | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs144575256; called by muse, mutect2, varscan2
- PPL | c.4252C>T p.R1418C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs772840383, COSV52173013; called by muse, mutect2, varscan2
- PPP6R2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as rs758787649, COSV53294377; called by muse, mutect2, varscan2
- PRKAA2 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV64806678; called by muse, mutect2, varscan2
- PROX1 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.771); catalogued as COSV54783765; called by muse, mutect2
- PRPF18 | c.108del p.E37Kfs*23 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs1261556843; called by mutect2, pindel, varscan2
- PRRC2B | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.53); catalogued as rs765308056, COSV61933826; called by mutect2, varscan2
- PSMD1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs776542337, COSV58078450, COSV58083546; called by muse, mutect2, varscan2
- PSMF1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs372603862; called by muse, mutect2, varscan2
- PTBP1 | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV62461861; called by muse, mutect2, varscan2
- PTCH2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs566147210, COSV64711001; called by muse, mutect2, varscan2
- PTK2 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV61792631; called by muse, mutect2, varscan2
- PTK7 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs748100799, COSV57851703; called by muse, mutect2, varscan2
- PTPN1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.544); catalogued as rs371730106; called by muse, mutect2, varscan2
- PTPRD | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1424143158, COSV61933737; called by muse, mutect2, varscan2
- PTPRK | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs771642405, COSV63907218; called by muse, mutect2, varscan2
- PUM2 | c.396del p.G133Afs*24 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs34931937; called by mutect2, pindel, varscan2
- PUS10 | c.1451+1G>A p.X484_splice | Splice Site (SNP) | VAF 31/146 reads (21%) | catalogued as rs766402169, COSV57454972, COSV57455239; called by muse, mutect2, varscan2
- PXDN | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs766902490, COSV53246259; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2862A>C p.E954D | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62787127; called by muse, mutect2, varscan2
- RAD51 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV51113991; called by muse, mutect2, varscan2
- RAI1 | c.2182T>C p.C728R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770814023, COSV55399318; called by muse, mutect2, varscan2
- RASSF5 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as rs570039354, COSV58798296; called by muse, mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 19/151 reads (13%) | catalogued as rs761285857; called by mutect2, varscan2
- RCC2 | c.1530G>T p.K510N | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100965134, COSV64906029, COSV64906344; called by muse, mutect2
- RDH12 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749038454, CM130717, COSV50822001; called by muse, mutect2, varscan2
- RESF1 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs757463058, COSV57024587, COSV57025804; called by muse, mutect2, varscan2
- REST | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58363030; called by muse, mutect2, varscan2
- RFX7 | c.991C>T p.R331C (on ENST00000559447 / NM_001368074.1; = p.R428C on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57968840; called by muse, mutect2, varscan2
- RGS11 | c.749C>T p.A250V (on ENST00000397770 / NM_183337.3; = p.A229V on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as rs756811171, COSV51454081; called by muse, mutect2, varscan2
- RHOD | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781618855, COSV58211967; called by muse, mutect2, varscan2
- RIMKLA | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68909988; called by muse, mutect2, varscan2
- RING1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1484062961, COSV63002971; called by muse, mutect2, varscan2
- RIT1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1420077819, COSV64171263; called by muse, mutect2
- RNF13 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs761261580, COSV53524993; called by muse, mutect2, varscan2
- RNF212 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs780533022, COSV67113665; called by muse, mutect2, varscan2
- RNF213 | c.8626dup p.H2876Pfs*15 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs757643496; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 60/171 reads (35%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNLS | c.216del p.K72Nfs*10 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs765347248, CX1212286; called by mutect2, pindel, varscan2
- ROBO4 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749338809, COSV60624136; called by muse, mutect2, varscan2
- ROCK1 | c.3284T>C p.L1095S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV67699418; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.3040A>T p.K1014* | Nonsense Mutation (SNP) | VAF 15/400 reads (4%) | catalogued as COSV64823333; called by muse, mutect2
- RPS6KA4 | c.788del p.P263Lfs*112 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | catalogued as COSV99589846; called by mutect2, pindel, varscan2
- RPS6KA5 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756086272, COSV56225720; called by muse, mutect2
- RPTOR | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs780248757, COSV60818409; called by muse, mutect2, varscan2
- RRH | c.324dup p.G109Wfs*23 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs751964437; called by mutect2, varscan2
- RRP12 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1286880149, COSV59667099; called by muse, mutect2, varscan2
- RYR1 | c.5011G>A p.A1671T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1316064829, COSV100616636, COSV62110536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD10 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs766038246, COSV53870408; called by muse, mutect2, varscan2
- SARAF | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367575463, COSV56357463; called by muse, mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN10A | c.3722C>A p.S1241Y | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71862678; called by muse, mutect2
- SDC3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs374473992, COSV100232409; called by muse, mutect2, varscan2
- SEC14L5 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs751387283, COSV52042071; called by muse, mutect2, varscan2
- SEMA4C | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs774137372, COSV59692297; called by muse, mutect2
- SERPINE2 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as COSV51460103; called by muse, mutect2, varscan2
- SH3BP5L | c.1130del p.G377Afs*152 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as COSV63540198; called by mutect2, varscan2
- SHH | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as COSV51920350; called by muse, mutect2, varscan2
- SHROOM2 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66610692; called by muse, mutect2, varscan2
- SIGLEC1 | c.2470del p.L824Wfs*36 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as COSV52460841; called by mutect2, pindel, varscan2
- SIGLEC1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144297916; called by muse, mutect2, varscan2
- SIGLEC14 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.222); catalogued as rs200742621, COSV55782040; called by muse, mutect2, varscan2
- SIPA1L3 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs368555030; called by muse, mutect2, varscan2
- SLAMF8 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs534230763, COSV56989929; called by muse, mutect2
- SLC25A22 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.779); catalogued as rs183409730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A53 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV62460827; called by muse, mutect2, varscan2
- SLC26A4 | c.965del p.N322Ifs*22 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs747834704; called by mutect2, pindel, varscan2
- SLC26A6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs775888818, COSV50840852; called by muse, mutect2, varscan2
- SLC27A1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53100786; called by muse, mutect2, varscan2
- SLC29A1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs190729620, COSV57580536; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- SLC5A10 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58762054; called by muse, mutect2, varscan2
- SLC5A7 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759833850, COSV50890378, COSV50910285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A3R2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs555526303, COSV54594391; called by muse, mutect2, varscan2
- SMARCA2 | c.3759del p.F1253Lfs*22 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV100571428; called by pindel, varscan2
- SMARCD2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs147427461, COSV56742075; called by muse, mutect2, varscan2
- SMC1B | c.3628C>T p.R1210* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as COSV53419546; called by muse, mutect2, varscan2
- SMG6 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778851052, COSV53976336; called by muse, mutect2, varscan2
- SMG7 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs750234937, COSV61634290; called by muse, mutect2, varscan2
- SMOX | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV53868368; called by muse, mutect2, varscan2
- SMTN | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs1206910466, COSV60783026; called by muse, mutect2
- SNRNP200 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60487348; called by muse, mutect2, varscan2
- SORBS3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754370780, COSV53554962; called by muse, mutect2, varscan2
- SORL1 | c.4867T>C p.Y1623H | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52762799; called by muse, mutect2, varscan2
- SOX6 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769385306, COSV57035700; called by muse, mutect2, varscan2
- SPATS2L | c.1157A>G p.N386S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62353001; called by muse, mutect2, varscan2
- SPEN | c.6313del p.A2105Lfs*33 | Frame Shift Del (DEL) | VAF 58/214 reads (27%) | catalogued as COSV65367511; called by mutect2, varscan2
- SPG11 | c.6991T>C p.F2331L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV56002073; called by muse, mutect2, varscan2
- SPICE1 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV55625107, COSV99870991; called by muse, mutect2, varscan2
- SPINT1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779767066, COSV59803410; called by muse, mutect2
- SPTBN1 | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV61694129; called by muse, mutect2, varscan2
- SRCIN1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1355463910; called by muse, mutect2, varscan2
- SRI | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs1457132903, COSV56000356; called by muse, mutect2, varscan2
- STK4 | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV65672108; called by muse, mutect2, varscan2
- STXBP3 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as rs147446724; called by muse, mutect2, varscan2
- SULT1E1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs753982089, COSV56946944; called by muse, mutect2, varscan2
- SYNE2 | c.6790A>G p.T2264A | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV59970511; called by muse, mutect2, varscan2
- SYNPO2 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs185497340, COSV61111823; called by muse, mutect2, varscan2
- SYT4 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54904176; called by muse, mutect2
- TAP2 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV66488406; called by muse, mutect2, varscan2
- TARS1 | c.1086C>T p.S362= | Splice Region (SNP) | VAF 24/72 reads (33%) | catalogued as rs757476719, COSV54312406; called by muse, mutect2, varscan2
- TBC1D14 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs374524981; called by muse, mutect2, varscan2
- TBC1D4 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs377319895; called by muse, mutect2, varscan2
- TBC1D9 | c.3280G>A p.V1094M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs368519500; called by muse, mutect2
- TCAP | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504427, CM062009, COSV54094138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX13A | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as COSV61182868; called by muse, mutect2, varscan2
- TFAP4 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs755945532, COSV52597153; called by muse, varscan2
- TFAP4 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52597307; called by muse, varscan2
- THOP1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs746532359, COSV57021170; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TINAGL1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as rs566858151, COSV54700029; called by muse, mutect2, varscan2
- TJP2 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as rs1014295697, COSV55262806, COSV55274381; called by muse, mutect2, varscan2
- TLN2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV60890205; called by muse, mutect2, varscan2
- TMC5 | c.2149G>A p.V717M (on ENST00000396229 / NM_001105248.1; = p.V471M on NM_024780.5) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769075056, COSV54909906; called by muse, mutect2, varscan2
- TMEM62 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752059710, COSV53040386; called by muse, mutect2
- TMPRSS9 | c.874G>A p.V292M (on ENST00000648592; = p.V258M on NM_182973.2) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.933); catalogued as rs571520737, COSV60227552; called by muse, mutect2, varscan2
- TNFRSF18 | c.298del p.V100Yfs*67 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs773489494; called by mutect2, pindel, varscan2
- TNFRSF4 | c.515del p.P172Qfs*? | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs769217131; called by mutect2, pindel, varscan2
- TNFSF11 | c.711A>T p.Q237H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53479937; called by muse, mutect2, varscan2
- TNFSF8 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV56344040; called by muse, mutect2, varscan2
- TOGARAM1 | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs756332417, COSV63895195; called by muse, mutect2, varscan2
- TPD52L3 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs771636693, COSV58829131; called by muse, mutect2, varscan2
- TRAK2 | c.2242C>T p.R748* | Nonsense Mutation (SNP) | VAF 57/235 reads (24%) | catalogued as rs199659556, COSV60271299; called by muse, mutect2, varscan2
- TRAPPC9 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768262663, COSV66893460; called by muse, mutect2, varscan2
- TRHDE | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs745929445, COSV53866204; called by muse, mutect2, varscan2
- TRIO | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60095768; called by muse, mutect2, varscan2
- TRPM2 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs146431153; called by muse, mutect2, varscan2
- TRPM6 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62522566; called by muse, mutect2, varscan2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/132 reads (26%) | catalogued as rs1401148397; called by mutect2, varscan2
- TSPAN11 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs746847398, COSV53821708; called by muse, mutect2, varscan2
- TSPOAP1 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs143530655; called by muse, mutect2, varscan2
- TSPOAP1 | c.4085del p.P1362Lfs*38 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as COSV52104623; called by mutect2, pindel, varscan2
- TTC17 | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as rs1209355193, COSV50005687; called by muse, mutect2, varscan2
- TTC3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.175); catalogued as rs779276502, COSV61289931; called by muse, mutect2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs751135082; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL12 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as rs1305488554, COSV53357366; called by muse, mutect2, varscan2
- TTN | c.36352G>A p.V12118I (on ENST00000591111; = p.V4694I on NM_003319.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | PolyPhen benign (0.292); catalogued as COSV60351763; called by muse, mutect2, varscan2
- TUBA3E | c.958del p.R320Gfs*59 | Frame Shift Del (DEL) | VAF 54/200 reads (27%) | catalogued as rs772219379; called by mutect2, pindel, varscan2
- TUBG2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764321349, COSV99258030; called by muse, mutect2, varscan2
- TUBGCP3 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758583156, COSV56191437; called by muse, mutect2, varscan2
- TUFT1 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs764426952, COSV61950521; called by muse, mutect2, varscan2
- UBA1 | c.2143C>T p.H715Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV60115559; called by muse, mutect2, varscan2
- UBE2U | c.595+2T>C p.X199_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV64281744; called by muse, mutect2, varscan2
- UBE3C | c.3052T>C p.C1018R | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61955662; called by muse, mutect2, varscan2
- UCMA | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753490238, COSV66321951; called by muse, mutect2, varscan2
- UGT2A3 | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52362152; called by muse, mutect2, varscan2
- UGT2B28 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59434450; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as rs767622329, COSV51960568; called by muse, mutect2, varscan2
- UMODL1 | c.453del p.R152Afs*26 | Frame Shift Del (DEL) | VAF 31/151 reads (21%) | catalogued as rs755485498; called by mutect2, pindel, varscan2
- UNC13A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as rs566299244, COSV53210618; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs767420916; called by mutect2, varscan2
- USP30 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV57451592; called by muse, mutect2
- USP31 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs780622514, COSV54857192; called by muse, mutect2, varscan2
- USP36 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs148226667; called by muse, mutect2, varscan2
- USP42 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs775947852, COSV60364398; called by muse, mutect2, varscan2
- USPL1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs994442881, COSV55000049, COSV55002409; called by muse, mutect2, varscan2
- VLDLR | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV101173246; called by muse, mutect2, varscan2
- VPS41 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV59653235; called by muse, mutect2, varscan2
- WDCP | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54593881; called by muse, mutect2, varscan2
- WDHD1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs145612447, COSV62214631; called by muse, mutect2
- WDR81 | c.4775del p.G1592Afs*11 (on ENST00000409644 / NM_001163809.2; = p.G541Afs*11 on NM_152348.4) | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | catalogued as COSV58487024; called by mutect2, pindel, varscan2
- WNK1 | c.7124del p.P2375Qfs*15 (on ENST00000315939 / NM_018979.4; = p.P2127Qfs*15 on NM_014823.3) | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as rs1565626263; called by mutect2, pindel, varscan2
- WNT6 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1172687654, COSV52111187; called by muse, mutect2, varscan2
- XIRP2 | c.140G>A p.R47Q (on ENST00000628543; = p.R222Q on NM_152381.6) | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534855387, COSV54721983, COSV54727923; called by muse, mutect2, varscan2
- XKR8 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs750423450, COSV65855347; called by muse, mutect2, varscan2
- XYLT1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs192917273, COSV54485773; called by muse, mutect2, varscan2
- YARS2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1251188344, COSV61402232; called by muse, mutect2, varscan2
- YIF1B | c.769G>A p.V257I (on ENST00000339413 / NM_001039673.3; = p.V242I on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs370851309; called by muse, mutect2, varscan2
- YTHDF2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1178225631, COSV65724183; called by muse, mutect2
- ZAN | c.3622G>A p.V1208M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as rs772882053, COSV61816593; called by muse, mutect2
- ZBTB12 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV64994218; called by muse, mutect2, varscan2
- ZC3H18 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs576458945, COSV56324181, COSV56328040; called by muse, mutect2
- ZFP37 | c.744dup p.H249Tfs*2 | Frame Shift Ins (INS) | VAF 17/166 reads (10%) | catalogued as rs1425115355; called by mutect2, pindel
- ZKSCAN2 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.383); catalogued as COSV60158758; called by muse, mutect2, varscan2
- ZMYM3 | c.143del p.P48Lfs*65 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs757506048; called by mutect2, pindel
- ZNF263 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 34/136 reads (25%) | catalogued as rs139107623; called by muse, mutect2, varscan2
- ZNF276 | c.1330G>A p.V444M (on ENST00000443381 / NM_001113525.2; = p.V369M on NM_152287.4) | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141797932; called by muse, mutect2, varscan2
- ZNF280C | c.564del p.K188Nfs*11 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | catalogued as rs770944520; called by mutect2, pindel, varscan2
- ZNF366 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs868490359, COSV59215293; called by muse, mutect2, varscan2
- ZNF454 | c.611del p.N204Mfs*52 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs752005964; called by mutect2, pindel, varscan2
- ZNF462 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs765625186, COSV52932019; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF530 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV60532487; called by muse, mutect2, varscan2
- ZNF549 | c.254C>T p.A85V (on ENST00000376233 / NM_001199295.2; = p.A72V on NM_153263.2) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779093977, COSV53724117; called by muse, mutect2, varscan2
- ZNF567 | c.756del p.K252Nfs*17 (on ENST00000536254 / NM_001322913.1; = p.K221Nfs*17 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs762873548; called by mutect2, varscan2
- ZNF599 | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs767378685, COSV61397467; called by muse, mutect2, varscan2
- ZNF701 | c.847C>T p.R283C (on ENST00000301093; = p.R217C on NM_018260.3) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148286783; called by muse, mutect2, varscan2
- ZNF708 | c.1405del p.I469Ffs*28 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs769330978; called by mutect2, pindel, varscan2
- ZNF765 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as COSV67183504; called by muse, mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF831 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64045341; called by muse, mutect2, varscan2
- A2M | c.3589del p.Y1197Tfs*12 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- ABL1 | c.1950del p.L651Wfs*43 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- ACSL1 | c.597del p.F199Lfs*12 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.563_565del p.S188del | In Frame Del (DEL) | VAF 22/87 reads (25%) | called by pindel, varscan2
- AFAP1L1 | c.368del p.P123Lfs*49 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- AGR3 | c.172del p.S58Vfs*5 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- ALPI | c.967del p.R323Afs*48 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, varscan2
- AMIGO3 | c.85dup p.R29Pfs*91 | Frame Shift Ins (INS) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- APEH | c.271del p.E91Nfs*3 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.2049dup p.S684Qfs*17 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- ASB15 | c.225del p.G76Dfs*40 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- ATAD1 | c.317_318del p.T106Sfs*12 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by pindel, varscan2
- ATAD5 | c.3794del p.N1265Ifs*45 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- CACNA1G | c.2483del p.G828Afs*11 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.2995C>T p.H999Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.171); called by muse, mutect2
- CBX4 | c.690del p.N231Tfs*3 | Frame Shift Del (DEL) | VAF 31/129 reads (24%) | called by mutect2, pindel, varscan2
- CC2D1A | c.1034dup p.R346Efs*57 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- CDH8 | c.286dup p.I96Nfs*8 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- CDKN1B | c.192dup p.Q65Sfs*60 | Frame Shift Ins (INS) | VAF 37/174 reads (21%) | called by mutect2, pindel, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, varscan2
- CFAP65 | c.5336_5337del p.E1779Gfs*25 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | called by pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | called by mutect2, varscan2
- CHD4 | c.2796del p.K932Nfs*28 (on ENST00000357008 / NM_001363606.2; = p.K945Nfs*28 on NM_001273.5) | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | called by mutect2, pindel, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- CNIH2 | c.167dup p.N56Kfs*59 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- COL7A1 | c.6017dup p.D2007Rfs*92 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by pindel, varscan2
- COL8A1 | c.2015del p.G672Afs*14 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- CPNE6 | c.243dup p.E82* | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | called by mutect2, varscan2
- CPSF6 | c.683del p.P228Hfs*14 | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | called by mutect2, pindel
- CUBN | c.2496del p.P833Lfs*67 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, varscan2
- CWC27 | c.864dup p.L289Ifs*10 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- DNHD1 | c.13795dup p.E4599Gfs*16 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- EFL1 | c.806dup p.D270Rfs*9 | Frame Shift Ins (INS) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- EIF2B2 | c.878_880del p.E293del | In Frame Del (DEL) | VAF 12/56 reads (21%) | called by pindel, varscan2
- EIF5B | c.3459del p.G1154Dfs*6 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- EPHB1 | c.244del p.A82Pfs*12 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- FAM186B | c.20del p.P7Hfs*4 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- FAM83H | c.74_75del p.K25Rfs*34 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- FBXO46 | c.1271del p.P424Rfs*34 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2
- GDF10 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GPAT4 | c.145del p.S49Vfs*3 | Frame Shift Del (DEL) | VAF 30/119 reads (25%) | called by mutect2, pindel, varscan2
- IL17RA | c.2199del p.M734Wfs*11 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 61/242 reads (25%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 46/102 reads (45%) | called by mutect2, varscan2
- KDM4B | c.152dup p.K52Efs*10 | Frame Shift Ins (INS) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.12286_12287del p.L4096Ifs*5 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- KIF17 | c.1546del p.Q516Rfs*95 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | called by mutect2, varscan2
- KLK8 | c.541dup p.Q181Pfs*5 | Frame Shift Ins (INS) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- LIPG | c.1391del p.T464Kfs*26 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- LMTK3 | c.3594del p.K1199Sfs*117 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- LPA | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 14/716 reads (2%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRFN3 | c.1199del p.P400Rfs*34 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, varscan2
- MACF1 | c.18301_18302del p.R6101Afs*5 (on ENST00000372915; = p.R4146Afs*5 on NM_012090.5) | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by pindel, varscan2
- MDC1 | c.3196del p.L1066Ffs*50 | Frame Shift Del (DEL) | VAF 42/198 reads (21%) | called by mutect2, pindel, varscan2
- NAT9 | c.584_585del p.E195Gfs*94 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- NLRP8 | c.1542dup p.A515Cfs*69 | Frame Shift Ins (INS) | VAF 61/268 reads (23%) | called by mutect2, pindel, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | called by mutect2, varscan2
- NOS3 | c.2526del p.G843Afs*115 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- NRG2 | c.922del p.E308Sfs*24 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- OLFML2A | c.1214del p.P405Lfs*2 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- OR6C65 | c.916del p.I306Yfs*4 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel
- PDS5A | c.2143dup p.Q715Pfs*36 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- PGBD2 | c.1102del p.V368* | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- PITPNC1 | c.787del p.L263Cfs*53 | Frame Shift Del (DEL) | VAF 43/183 reads (23%) | called by mutect2, pindel, varscan2
- PKN1 | c.1061del p.P354Qfs*8 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 64/238 reads (27%) | called by mutect2, varscan2
- PRAG1 | c.3242del p.P1081Lfs*56 | Frame Shift Del (DEL) | VAF 18/171 reads (11%) | called by mutect2, pindel, varscan2
- RAMP2 | c.168del p.X56_splice | Splice Site (DEL) | VAF 26/169 reads (15%) | called by mutect2, pindel, varscan2
- RANBP2 | c.7866del p.K2622Nfs*17 | Frame Shift Del (DEL) | VAF 50/201 reads (25%) | called by mutect2, pindel, varscan2
- RB1 | c.1848dup p.G617Rfs*36 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4594del p.S1532Vfs*30 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, varscan2
- RECQL4 | c.237del p.H81Ifs*2 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- RNF31 | c.1204del p.D402Mfs*90 | Frame Shift Del (DEL) | VAF 58/222 reads (26%) | called by mutect2, pindel, varscan2
- RPUSD3 | c.206del p.N69Tfs*22 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, varscan2
- SCUBE3 | c.536del p.G179Vfs*21 | Frame Shift Del (DEL) | VAF 29/157 reads (18%) | called by mutect2, pindel, varscan2
- SDK1 | c.1211_1212del p.V404Gfs*59 | Frame Shift Del (DEL) | VAF 28/158 reads (18%) | called by pindel, varscan2
- SECTM1 | c.16dup p.L6Pfs*26 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel
- SETX | c.5243del p.F1748Sfs*3 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- SIRT1 | c.766del p.I256Lfs*2 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- SOD2 | c.584del p.N195Mfs*7 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- SPEN | c.6750del p.A2251Qfs*102 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | called by mutect2, pindel, varscan2
- STAC3 | c.721-17_738del p.X241_splice | Splice Site (DEL) | VAF 21/242 reads (9%) | called by mutect2, pindel
- TACC2 | c.6446del p.P2149Qfs*2 (on ENST00000334433; = p.P227Qfs*2 on NM_006997.4) | Frame Shift Del (DEL) | VAF 56/202 reads (28%) | called by mutect2, varscan2
- TBX19 | c.1228del p.E410Sfs*4 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- TESMIN | c.257del p.G86Afs*70 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- TGFBI | c.428del p.P143Lfs*39 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- TMCO4 | c.1788_1791del p.P597Lfs*83 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- TMEM100 | c.177del p.F60Lfs*41 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, pindel, varscan2
- TMEM132D | c.618del p.T207Rfs*75 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- TNIP1 | c.1863del p.R621Sfs*33 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.3050del p.N1017Mfs*20 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.97013dup p.E32339Rfs*6 (on ENST00000591111; = p.E24915Rfs*6 on NM_003319.4) | Frame Shift Ins (INS) | VAF 8/75 reads (11%) | called by mutect2, pindel
- TTN | c.60774dup p.D20259Rfs*40 (on ENST00000591111; = p.D12835Rfs*40 on NM_003319.4) | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TTN | c.7322_7323del p.S2441Cfs*3 (on ENST00000591111; = p.S2395Cfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by pindel, varscan2
- UCP3 | c.769del p.L257Sfs*4 | Frame Shift Del (DEL) | VAF 38/188 reads (20%) | called by mutect2, pindel, varscan2
- URGCP | c.1495del p.D499Tfs*30 (on ENST00000453200 / NM_001077663.3; = p.D490Tfs*30 on NM_017920.4) | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | called by mutect2, pindel, varscan2
- VPS13B | c.11961del p.S3988Pfs*25 | Frame Shift Del (DEL) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- VPS26B | c.61_62del p.S21* | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by pindel, varscan2
- ZNF292 | c.3470del p.L1157Cfs*5 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- ZNF609 | c.1235del p.G412Afs*39 | Frame Shift Del (DEL) | VAF 30/179 reads (17%) | called by mutect2, pindel, varscan2
- ZNF670 | c.709del p.S237Pfs*48 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- ABCA1 | c.1014C>T p.G338= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV66070712; called by muse, mutect2
- ABCG8 | c.1227C>T p.N409= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs774459606, COSV55393870; called by muse, mutect2, varscan2
- AC068580.4 | c.375C>T p.S125= | Silent (SNP) | VAF 89/289 reads (31%) | catalogued as rs987735225, COSV52587275; called by muse, mutect2, varscan2
- AC098582.1 | c.1050C>T p.G350= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs779712451, COSV52024678; called by muse, mutect2, varscan2
- ADAM19 | c.354G>A p.T118= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs141005435, COSV57436088; called by muse, mutect2, varscan2
- ADGRF2 | c.903C>T p.N301= (on ENST00000296862 / NM_001368115.2; = p.N233= on NM_153839.7) | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV57287024, COSV99731990; called by muse, mutect2, varscan2
- AIFM2 | c.168C>T p.S56= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs770190495, COSV100325850, COSV57160965; called by muse, mutect2
- AIFM3 | c.877C>T p.L293= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100105192, COSV59004212; called by muse, mutect2, varscan2
- AKAP1 | c.2310G>A p.A770= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs377588182; called by muse, mutect2, varscan2
- AKNA | c.3666C>T p.H1222= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs778455451, COSV56337156; called by muse, mutect2, varscan2
- AMPD3 | c.498G>A p.A166= (on ENST00000396553 / NM_001025389.2; = p.A175= on NM_000480.3) | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as rs147701905; ClinVar: uncertain significance; called by muse, varscan2
- ANKFN1 | c.1125C>T p.D375= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs759462310, COSV59459991, COSV59461321; called by muse, mutect2, varscan2
- AP3D1 | c.2058G>A p.S686= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs373890557; called by muse, mutect2, varscan2
- ARHGEF18 | c.669G>A p.T223= (on ENST00000359920 / NM_001130955.2; = p.T119= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs748470220, COSV60473607, COSV60473993; called by muse, mutect2, varscan2
- ARMC5 | c.738G>T p.L246= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV51660054; called by muse, mutect2, varscan2
- ARPIN | c.225C>T p.D75= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs531934995, COSV62589799; called by muse, mutect2, varscan2
- ASAP2 | c.2319C>T p.P773= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1354685733, COSV55638732, COSV99856993; called by muse, mutect2, varscan2
- ASPSCR1 | c.738G>A p.S246= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs759475392, COSV60731258; called by muse, mutect2
- ATP10A | c.2475C>T p.C825= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV63524539; called by muse, mutect2, varscan2
- ATP8B2 | c.3558G>A p.A1186= (on ENST00000672630; = p.A1153= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs557794271, COSV63833873; called by muse, mutect2, varscan2
- AVPR1A | c.960C>T p.S320= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs1341247447, COSV54548065; called by muse, mutect2, varscan2
- BCL3 | c.555G>A p.P185= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1350084194, COSV51235035; called by muse, mutect2, varscan2
- BPIFB6 | c.48G>A p.T16= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs774189878, COSV62756674; called by muse, mutect2, varscan2
- BYSL | c.1173C>T p.A391= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as rs908093306, COSV57829414; called by muse, mutect2, varscan2
- C16orf87 | c.414C>T p.V138= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs368374110; called by muse, mutect2, varscan2
- C20orf141 | c.396C>T p.D132= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs574582071, COSV63028655; called by muse, mutect2, varscan2
- C2CD2L | c.1644C>T p.D548= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as rs199873574; called by muse, mutect2, varscan2
- CADPS2 | c.2421C>T p.L807= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs376933238, COSV57350340; called by muse, mutect2, varscan2
- CAMSAP3 | c.2247G>A p.T749= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs555103286, COSV50367034; called by muse, mutect2, varscan2
- CASKIN2 | c.2898C>T p.P966= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs981892810, COSV58600056; called by muse, mutect2, varscan2
- CCDC180 | c.1152G>A p.K384= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as COSV63835369; called by muse, mutect2, varscan2
- CDH15 | c.111G>A p.A37= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as rs373216025; called by muse, mutect2, varscan2
- CDK18 | c.1272G>A p.L424= (on ENST00000506784 / NM_212503.3; = p.L394= on NM_002596.4) | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV63727834; called by muse, mutect2
- CEP135 | c.1854T>C p.H618= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CEP162 | c.1887G>A p.A629= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs758105941, COSV57620527, COSV57624727; called by muse, mutect2, varscan2
- CFAP251 | c.174C>T p.G58= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs370060195, COSV55840268; called by muse, mutect2, varscan2
- CKMT2 | c.195C>T p.A65= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs200789133, COSV54175043; called by muse, mutect2, varscan2
- CLCA4 | c.1842C>T p.Y614= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs372874690; called by muse, mutect2, varscan2
- CLVS2 | c.126G>A p.P42= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs560066128, COSV51569024; called by muse, mutect2, varscan2
- CRHR1 | c.630C>T p.H210= (on ENST00000398285 / NM_001145146.2; = p.H181= on NM_004382.5) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV53286184; called by muse, mutect2
- DCP2 | c.303T>C p.G101= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs1284832346, COSV66618321; called by muse, mutect2, varscan2
- DENND4B | c.1287G>A p.R429= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1262825724, COSV63411971; called by muse, mutect2, varscan2
- DEPDC5 | c.1182C>T p.G394= | Silent (SNP) | VAF 21/227 reads (9%) | catalogued as rs1289456216, COSV56703043; ClinVar: uncertain significance; called by muse, mutect2
- DNAH2 | c.5643C>T p.A1881= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs144218986; called by muse, mutect2, varscan2
- DNAI1 | c.1941C>T p.G647= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1022057422, COSV54284826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPH5 | c.681C>T p.A227= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs1245821332, COSV59860411; called by muse, mutect2, varscan2
- DSC2 | c.1707C>T p.D569= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs201517977, COSV51862009; called by muse, mutect2, varscan2
- DZIP3 | c.2559C>T p.N853= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs371315606; called by muse, mutect2, varscan2
- EEF1B2 | c.102T>C p.D34= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV51913802; called by muse, mutect2, varscan2
- EMILIN2 | c.996C>T p.G332= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as rs560726648, COSV54427638; called by muse, mutect2, varscan2
- EPHB2 | c.2319C>T p.D773= (on ENST00000400191 / NM_001309193.2; = p.D774= on NM_004442.7) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs141632768; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPS8L2 | c.300G>A p.S100= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as rs971698838, COSV59350208; called by muse, mutect2
163 further variants in this file (0 protein-altering or splice-affecting, 146 silent, 17 other) are not listed here.
